Surgical pathology report (de-identified scan), TCGA case TCGA-AZ-6598, project TCGA-COAD (Colon Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-AZ-6598-01A (Primary Tumor).

PATIENT HISTORY:

Colon cancer, COPD, thoraco of abdominal aneurysm.

PRE OP DIAGNOSIS: Cecal mass.

POST OP DIAGNOSIS: Same.

PROCEDURE: Right hemicolectomy.

ADDENDA:**Addendum**

In situ hybridization studies performed on the moderately differentiated adenocarcinoma of the right colon show a ratio of Her-2/neu gene to the centromere of chromosome 17 of 1.66. This indicates low level amplification of the Her-2/neu oncogene in the targeted region.

FINAL DIAGNOSIS:**PART 1: COLON, RIGHT, HEMICOLECTOMY –**

- A. MODERATELY DIFFERENTIATED ADENOCARCINOMA.
- B. TUMOR SIZE 6.0 X 6.0 X 5.0 CM.
- C. TUMOR INVADING THROUGH THE MUSCULARIS PROPRIA TO THE SUBSEROAL ADIPOSE TISSUE.
- D. SURGICAL MARGINS FREE OF TUMOR.
- E. NO EVIDENCE OF ANGIOLYMPHATIC OR PERINEURAL INVASION.
- F. TWENTY-FOUR (24) LYMPH NODES FREE OF TUMOR.
- G. TUMOR STAGE: pT3N0MX

PART 2: GALLBLADDER, CHOLECYSTECTOMY –

- A. CHOLELITHIASIS WITH CHRONIC CHOLECYSTITIS.
- B. NO EVIDENCE OF MALIGNANCY.

COMMENT:

Part 1: Multiple sections of the right colon tumor mass show a moderately differentiated adenocarcinoma consisting of well-formed malignant glands. In some area, the tumor cells contain abundant mucin vacuoles with a signet-ring appearance. However, individual infiltrating signet-ring cells are not seen. In other areas, the tumor cells form nests or trabeculae with irregular to angular nuclei and visible nucleoli. Although the latter component raises the possibility of neuroendocrine differentiation, immunostains for the neuroendocrine markers synaptophysin and chromogranin are both negative. Therefore, this tumor is best characterized as moderately differentiated adenocarcinoma. [REDACTED] has reviewed this case and agreed with the diagnosis.

SYNOPTIC - PRIMARY COLON AND RECTAL TUMORS

- A. Location: 2
- 1. Ileocecal Region
- 2. Ascending Colon
- 3. Transverse Colon
- 4. Descending Colon
- 5. Sigmoid Colon
- 6. Rectum
- B. Procedure: 1
- 1. Segmental Colectomy
- 2. Total Colectomy
- 3. Other
- C. Size of Tumor (maximum dimension): 6.0 x 6.0 x 5.0 cm
- D. Type: 1
- 1. Adenocarcinoma, NOS
- 2. Adenocarcinoma arising in a background of an adenoma.
- 3. Adenocarcinoma arising in a background of inflammatory bowel disease
- 4. Adenosquamous carcinoma
- 5. Carcinoid Tumor (Neuroendocrine Tumor)
- 6. Mucinous Adenocarcinoma
- 7. Signet ring cell type Adenocarcinoma
- 8. Neuroendocrine Carcinoma
- 9. Squamous Cell Carcinoma
- 10. Undifferentiated Carcinoma
- 11. Sarcoma
- 12. Smooth Muscle Tumor
- 13. Gastrointestinal stromal tumor
- 14. Lymphoma
- 15. Other
- E. Grade: 2
- 1. Well differentiated
- 2. Moderately differentiated
- 3. Poorly differentiated
- F. Extent of Infiltration: 4
- 1. Limited to the mucosa
- 2. Into submucosa
- 3. Involving muscularis propria
- 4. Infiltrating through muscularis propria into serosal adipose tissue
- 5. Involving adjacent organs/ pelvic wall
- G. Angiolymphatic Invasion: 2
- 1. Yes
- 2. No
- H. Surgical Margins Involved: 2
- 1. Yes
- 2. No
- I. Regional Lymph Node Involvement: 2
- 1. Yes
- 2. No
- J. If regional lymph nodes involved, Number positive/number examined: # / #.
- K. Extracapsular spread: 2
- Yes
- 2. No
- L. Associated conditions: N / A
- 1. Ulcerative colitis.
- 2. Crohns Disease.
- 3. History/ presence of adenomatous polyps.
- 4. Multiple polyposis syndromes.
- 5. Diverticulosis.
- M. TNM Stage: T 3 N 0 M X
- N. Dukes' Stage: 2
- 1. A (limited to mucosa and muscularis)
- 2. B (through muscularis into subserosa)
- 3. C (through subserosa and involving adjacent organ/pelvic wall/regional or distant lymph nodes)
- O. Astler - Collier Stage: 3
- 1. A (mucosa but not into muscularis propria)
- 2. B1 (muscularis propria but not through, LN negative)
- 3. B2 (through muscularis propria into subserosal fibroadipose tissue, LN negative)
- 4. C1 (limited to muscularis propria but not through serosa, LN positive)
- 5. C2 (invades serosal adipose tissue, LN positive)

Source: NCI Genomic Data Commons file 4e9fbc01-af94-4bf7-99b5-750655addfb5 (TCGA-AZ-6598.7D5CE419-6678-4CD8-89A9-31E8BBB8406F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).